Gene-level copy-number profile of tumor specimen ALCH-AD0T-TTP1-A from ALCHEMIST case ALCH-AD0T, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.6 years (19,204 days).
Specimen ALCH-AD0T-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0cda5cf1-84db-4629-8171-122a842d9964.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AD0T-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/3e15d63d-4444-4e3c-8fb9-f0823226c548

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 3,732; copy number 2: 50,609; copy number 3: 3,995; copy number 4: 7; copy number 6: 1; copy number 7: 1; copy number 8: 2; copy number 14: 1; copy number 16: 12; copy number 18: 2; copy number 44: 1.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,693,124–7,694,844, 1 gene (within-gene range 0–2): AL359881.3.
- chr9:41,340,823–41,355,538, 1 gene: CDRT15P6.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–1): CRB2.
- chr10:133,295,187–133,295,977, 1 gene (within-gene range 0–1): AL360181.2.
- chr12:122,834,453–122,862,961, 1 gene: HIP1R.
- chr15:25,170,723–25,204,438, 19 genes (within-gene range 0–2): SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19.
- chr17:64,778,842–64,778,937, 1 gene (within-gene range 0–2): AC103810.3.
- chr19:33,299,934–33,301,168, 1 gene (within-gene range 0–2): AC008738.3.
- chr20:3,227,417–3,239,559, 1 gene: SLC4A11.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 20 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,280,436–1,292,029, 1 gene, copy number 6: SCNN1D.
- chr16:16,290,135–16,398,594, 14 genes, copy number 8–16 (within-gene range 4–16): AC136624.2, MIR3179-2, MIR3670-2, AC138969.2, MIR3180-2, PKD1P1, Y_RNA, AC138969.1, MIR6511A2, MIR6770-2, AC138969.3, MIR6511A3, NPIPA7, AC136619.1.
- chr21:44,107,373–44,210,114, 2 genes, copy number 14–44 (within-gene range 3–44): PWP2, GATD3A.
- chr21:44,172,169–44,207,399, 3 genes, copy number 7–18: AP001056.2, AP001056.1, AP001057.1.

Autosomal genes at a single copy (total copy number 1): 3,731. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
